Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9H2, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9H2-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Final Diagnosis

- A. LIVER, LEFT LATERAL SEGMENT 3, EXCISIONAL BIOPSY:
Bile duct hamartoma.
- B. LIVER, LEFT LATERAL SEGMENT, EXCISION:
Benign hepatic parenchyma, negative for carcinoma.
- C. LYMPH NODE, PERIportal ADENOPATHY:
One lymph node free of malignancy (0/1).
- D. LIVER AND GALLBLADDER, LIVER SEGMENTS 4B AND 5, HEPATIC SEGMENTECTOMY AND CHOLECYSTECTOMY:
Hepatocellular carcinoma, poorly differentiated, with sclerotic stroma.
Carcinoma invades into the subserosa of the gallbladder.
Perineural invasion identified.
No lymphatic or venous invasion identified.
Hepatic parenchymal margin is free of malignancy, see Key Pathological Findings.

I, the attending pathologist, personally reviewed the entire case and rendered the final diagnosis. Electronically Signed Out by

Key Pathological Findings

D: Liver, Resection, Synoptic Data
SPECIMEN TYPE: 4B AND 5 SEGMENTECTOMY
FOCALITY:
Solitary (specify location): segment 4b and 5
TUMOR SIZE: 3.4 cm
HISTOLOGIC TYPE:
Hepatocellular carcinoma
HISTOLOGIC GRADE: GIII: Poorly differentiated
PRIMARY TUMOR (pT): pT1: Solitary tumor with no vascular invasion
REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis
Number examined: 1
Number involved: 0
DISTANT METASTASIS (pM): pMX: Cannot be assessed
MARGINS:
Parenchymal margin uninvolved by invasive carcinoma
Bile duct margin cannot be assessed
*VENOUS (LARGE VESSEL) INVASION (V): *Absent
*ADDITIONAL PATHOLOGIC FINDINGS:
*None identified

ICD-O-3
Carcinoma, hepatocellular NOS
8170B
Site: Liver C22.0
9/24/28/14

Specimen(s) Received

- A LEFT LATERAL SEGMENT 3 EXCISIONAL BX OF LIVER FS
B LEFT LATERAL SEGMENT 2 NODULE FS
C PERIportal ADENOPATHY FS

[page 2 of 3]
D LIVER SEGMENT 4B AND 5 AND GALLBLADDER - GROSS EXAM

Clinical History

HCC.

Preoperative Diagnosis

Hepatocellular carcinoma.

Frozen Section Diagnosis

FSA1 LEFT LATERAL SEGMENT 3:
Bile duct hamartoma.

FSB1 LEFT LATERAL SEGMENT 2 NODULE:
Negative for carcinoma.

FSC1 PERIportal ADENOPATHY:
Reactive lymph node. No evidence of malignancy.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by
in at per

Intraoperative Consultation

D LIVER AND GALLBLADDER:
Lesion grossly measures 1.1 cm from parenchymal margin.

Gross Description

A. Specimen A is received fresh for frozen section labeled "left lateral segment 3 excisional biopsy." The specimen consists of a 1.5 x 1.0 x 0.5-cm, tan-gray, soft tissue, which is entirely submitted for frozen section labeled FSA1.

B. Specimen B is received fresh for frozen section labeled "left lateral segment 2 nodule." The specimen consists of a 1.2 x 0.3 x 0.2-cm, tan-gray, soft tissue, which is entirely submitted for frozen section labeled FSB1.

C. Specimen C is received fresh for frozen section labeled "periportal adenopathy." The specimen consists of a 1.8-cm lymph node with a small amount of attached fat. The lymph node is bisected and entirely submitted for frozen section labeled FSC1.

D. Specimen D is received fresh labeled "liver segment 4B and 5, and gallbladder." The specimen consists of a 116-g, 8.6 x 5.1 x 4.3-cm wedge of liver with an adherent 8.7 x 3.3 x 2.2-cm gallbladder. The capsule is indurated surrounding the adherent gallbladder with a small amount of attached fat. Sectioning through the liver at the adherent gallbladder reveals a circumscribed, 3.4 x 2.7 x 2.4-cm, gray-white tumor, which extends to the overlying capsule to the soft tissue surrounding the gallbladder. No extension into the gallbladder wall is identified. The tumor is 1.1 cm from the

[page 3 of 3]
parenchymal margin. The surrounding parenchyma is dense, tan-brown. On opening the gallbladder, the lumen contains a small amount of viscous, green-black bile. The mucosal surface is granular, tan-green, and the wall measures 0.1 cm in thickness. The fat adjacent to the neck of the neck of the gallbladder is focally indurated. The medial parenchymal margin is inked red, lateral yellow, superior blue, and deep black. The fat attached to the liver capsule is inked green. Representative sections are submitted labeled.

- D1-3: Tumor to adherent gallbladder
- D4: Tumor to closest parenchymal margin
- D5: Tumor to adherent fat
- D6: Lumen at parenchymal margin
- D7: Tumor to capsule and adjacent parenchyma
- D8: Gallbladder, cystic duct margin
- D9: Fat attached to gallbladder neck
- D10-11: Fat attached to liver capsule

Tissue from specimen D is submitted to tissue procurement laboratory.

Source: NCI Genomic Data Commons file 207640da-0c4b-48b7-9980-02e0da418174 (TCGA-2Y-A9H2.4C19CF84-5E30-4854-A084-F6EE53A80543.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).